Gene-level copy-number profile of tumor specimen TCGA-CN-6992-01A from TCGA case TCGA-CN-6992, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.9 years (22,598 days).
Specimen TCGA-CN-6992-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.95b8dc52-6031-4571-b432-132276959b23.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6992-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef7ac65b-f1aa-4777-b730-434f1c2d09f4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 2; copy number 2: 19,076; copy number 3: 1,819; copy number 4: 31,892; copy number 5: 1,977; copy number 6: 2,602; copy number 7: 420; copy number 8: 997; copy number 9: 222; copy number 10: 300; copy number 11: 201; copy number 12: 41; copy number 14: 192; copy number 16: 4; copy number 18: 5; copy number 20: 19; copy number 22: 1; copy number 27: 6; copy number 38: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6992-01A-11D-1910-01): tumor purity 0.57, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–1,550,103, 31 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1.
- chr11:129,030,459–129,030,572, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 992 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,474,825–40,474,059, 65 genes, copy number 11 (broad region; genes not listed).
- chr3:105,366,909–106,427,977, 5 genes, copy number 10–12: ALCAM, CBLB, AC131237.1, AC079382.1, AC079382.2.
- chr3:148,368,384–162,601,792, 254 genes, copy number 9–10 (broad region; genes not listed).
- chr3:167,392,796–182,740,848, 239 genes, copy number 10–14 (broad region; genes not listed).
- chr4:128,269,237–129,377,504, 16 genes, copy number 11–16: PGRMC2, LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2.
- chr7:52,165,235–54,812,727, 31 genes, copy number 10–20 (within-gene range 5–20): AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT.
- chr7:68,723,911–69,597,493, 11 genes, copy number 12: RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr7:79,124,739–79,357,594, 5 genes, copy number 18: AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1.
- chr7:81,175,508–82,443,777, 10 genes, copy number 16–38: AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 9 (within-gene range 6–9): UNC5D.
- chr8:35,525,176–38,853,028, 77 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:13,152,200–13,152,348, 1 gene, copy number 14: AC022878.1.
- chr15:100,716,249–101,933,350, 45 genes, copy number 11: AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr18:31,318,160–48,963,941, 232 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
